Somatic mutation profile of tumor specimen TCGA-HF-7131-01A (aliquot TCGA-HF-7131-01A-11D-2053-08) from TCGA case TCGA-HF-7131, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2.
Specimen TCGA-HF-7131-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1f9cd83-5e15-4152-a52d-debe394b20ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HF-7131-10A (Blood Derived Normal), aliquot TCGA-HF-7131-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/211973a4-af24-4011-a653-3a53f4755440

The open-access MAF lists 99 somatic variants for this specimen: 72 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 23, Nonsense Mutation 5, Frame Shift Del 3, Intron 2, RNA 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL5 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100389153; called by muse, mutect2, varscan2
- ADCY10 | c.2383C>T p.H795Y | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100896827; called by muse, mutect2, varscan2
- ANO2 | c.268G>A p.D90N (on ENST00000356134 / NM_001278597.3; = p.D94N on NM_001278596.3) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100500768; called by muse, mutect2, varscan2
- ASXL3 | c.5485A>C p.K1829Q | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV99323764; called by muse, mutect2, varscan2
- ATR | c.7345T>C p.S2449P | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100638178; called by muse, mutect2, varscan2
- B4GALT1 | c.1071C>A p.D357E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.171); catalogued as rs1296980083, COSV101122981; called by muse, mutect2
- BCL6B | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 62/134 reads (46%) | catalogued as COSV99546599; called by muse, mutect2, varscan2
- CCNA1 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV99714547; called by muse, mutect2, varscan2
- CERS2 | c.995C>T p.T332I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV99644505; called by muse, mutect2, varscan2
- CPT1C | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54920363; called by muse, mutect2, varscan2
- CROCC | c.4633G>A p.E1545K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as rs1193487347, COSV100978197, COSV65011610; called by muse, mutect2, varscan2
- CSMD3 | c.5669T>C p.I1890T (on ENST00000297405 / NM_001363185.1; = p.I1786T on NM_052900.3) | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV99833067; called by muse, mutect2
- CYP2A13 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.111); catalogued as rs981836979, COSV100386793; called by muse, mutect2, varscan2
- DCAF5 | c.1921G>C p.E641Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.152); catalogued as COSV100432430; called by muse, mutect2, varscan2
- DEFB110 | c.14T>G p.L5R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100953778, COSV100953830; called by muse, mutect2, varscan2
- DHX8 | c.3565C>G p.L1189V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as COSV99292200; called by muse, mutect2, varscan2
- DISP2 | c.1297C>T p.L433F | Missense Mutation (SNP) | VAF 131/375 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51116401, COSV99139953; called by muse, mutect2, varscan2
- DNAH9 | c.10643A>C p.K3548T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52335697; called by muse, mutect2, varscan2
- DOCK8 | c.6098G>A p.R2033H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs558033558, COSV101209910; ClinVar: uncertain significance; called by muse, varscan2
- DPP3 | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV100855584; called by muse, mutect2
- ERCC6 | c.2352A>C p.E784D | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.23); catalogued as rs767691315, COSV100875903; called by muse, mutect2, varscan2
- FAT3 | c.10205A>C p.K3402T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99965584; called by muse, mutect2, varscan2
- FBXO42 | c.305T>G p.I102S | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as COSV100981742; called by muse, mutect2, varscan2
- FHL5 | c.814T>G p.F272V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100459374; called by muse, mutect2, varscan2
- FRMD3 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100418603, COSV58462757; called by muse, mutect2, varscan2
- GINM1 | c.180+2T>C p.X60_splice | Splice Site (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100805313; called by muse, mutect2, varscan2
- IFT57 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99197471; called by muse, mutect2, varscan2
- KCNJ5 | c.1196A>G p.E399G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV100610651; called by muse, mutect2
- KIAA1549L | c.3286C>A p.Q1096K (on ENST00000321505; = p.Q1393K on NM_012194.3) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99683393; called by muse, mutect2, varscan2
- KIF26B | c.5977G>A p.E1993K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100832264; called by muse, mutect2, varscan2
- MCU | c.899T>C p.L300S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100849169; called by muse, mutect2, varscan2
- MMP2 | c.698G>A p.C233Y | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54599758, COSV99527738; called by muse, mutect2, varscan2
- MMRN1 | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as COSV99307041; called by muse, mutect2, varscan2
- MSH3 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143211109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.4000A>C p.S1334R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV101199725, COSV67489104; called by muse, mutect2, varscan2
- MYOM2 | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 98/392 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as rs1474471893, COSV50715374; called by muse, mutect2, varscan2
- NECAB3 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1410781545, COSV99864728; called by muse, mutect2, varscan2
- NLGN4X | c.1952A>T p.K651M | Missense Mutation (SNP) | VAF 99/252 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99321553; called by muse, mutect2, varscan2
- NLRP2 | c.1360G>T p.A454S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99672239; called by muse, mutect2, varscan2
- NLRP8 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.177); catalogued as rs759351908, COSV52585627; called by muse, mutect2, varscan2
- NMRK2 | c.464A>C p.K155T | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99396331; called by muse, mutect2, varscan2
- OGA | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV100761765; called by muse, mutect2, varscan2
- OR7C1 | c.688T>G p.S230A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV99934869; called by muse, mutect2, varscan2
- PATJ | c.4105G>T p.E1369* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100219594; called by muse, mutect2, varscan2
- PIK3C2A | c.3371T>C p.V1124A | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.452); catalogued as COSV99790664; called by muse, mutect2, varscan2
- PPP2R5D | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100028684; called by muse, mutect2, varscan2
- PRKG2 | c.2183T>A p.L728* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100019786; called by muse, mutect2, varscan2
- PRRX1 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53410909, COSV99509643; called by muse, mutect2, varscan2
- RIC8A | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100254793; called by muse, mutect2, varscan2
- RNASE11 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV100250512; called by muse, mutect2, varscan2
- RPS2 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV51910120, COSV51910970; called by muse, mutect2, varscan2
- SARDH | c.2163G>C p.L721= | Splice Region (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100898389, COSV64100304; called by muse, mutect2, varscan2
- SIPA1L1 | c.3244C>G p.P1082A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.157); catalogued as COSV100665482; called by muse, mutect2, varscan2
- SMARCAD1 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.069); catalogued as COSV100758899; called by muse, mutect2, varscan2
- SMC3 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.205); catalogued as COSV100699903; called by muse, mutect2, varscan2
- SPTA1 | c.3952G>T p.A1318S | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63752853, COSV63756067; called by muse, mutect2, varscan2
- ST8SIA6 | c.549T>A p.Y183* | Nonsense Mutation (SNP) | VAF 31/137 reads (23%) | catalogued as COSV101112138; called by muse, mutect2, varscan2
- TCTN2 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1222611018, COSV100315201; called by muse, mutect2, varscan2
- TEX15 | c.7729G>T p.E2577* (on ENST00000256246; = p.E2960* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 36/129 reads (28%) | catalogued as COSV99821279; called by muse, mutect2, varscan2
- TIAM1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV99734806; called by muse, mutect2, varscan2
- TMC2 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs372275239; called by muse, mutect2, varscan2
- TP53 | c.383del p.P128Lfs*42 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as COSV53283607; called by mutect2, pindel, varscan2
- TTN | c.63073G>T p.A21025S (on ENST00000591111; = p.A13601S on NM_003319.4) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | PolyPhen benign (0.022); catalogued as COSV100610619; called by muse, mutect2, varscan2
- UBQLN2 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100592705; called by muse, mutect2, varscan2
- ZNF99 | c.1396T>G p.S466A | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV101233815; called by muse, mutect2, varscan2
- ZNF99 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.194); catalogued as COSV68056483; called by muse, mutect2, varscan2
- DCAF1 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2
- EIF3I | c.549_555del p.N183Kfs*16 | Frame Shift Del (DEL) | VAF 17/129 reads (13%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.446G>C p.R149T | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NBPF26 | c.2617G>A p.D873N (on ENST00000620612; = p.D611N on NM_001351372.1) | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- USP29 | c.926_927del p.F309Cfs*2 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | called by mutect2, pindel, varscan2
- ARMC4 | c.2194T>C p.L732= | Silent (SNP) | VAF 52/201 reads (26%) | catalogued as COSV59473310; called by muse, mutect2, varscan2
- CFAP94 | c.1785T>G p.A595= (on ENST00000320267 / NM_001352064.2; = p.A601= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs764045877, COSV100209047; called by muse, mutect2, varscan2
- DEPTOR | c.171C>T p.L57= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV53813254, COSV53822466; called by muse, mutect2, varscan2
- HELB | c.1533G>A p.Q511= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV99921878; called by muse, mutect2, varscan2
- IVL | c.1677G>T p.L559= | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as COSV100908154; called by muse, mutect2, varscan2
- KDR | c.348C>G p.V116= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV99817534; called by muse, mutect2, varscan2
- KNSTRN | c.36T>A p.V12= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99991848; called by muse, mutect2, varscan2
- LILRB2 | c.579G>A p.S193= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as rs370713732, COSV58744722; called by muse, mutect2, varscan2
- MAB21L2 | c.357G>A p.A119= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as rs767785923, COSV100462125; called by muse, mutect2, varscan2
- MBOAT7 | c.1147C>T p.L383= | Silent (SNP) | VAF 32/123 reads (26%) | catalogued as rs760617583, COSV99824787; called by muse, varscan2
- MED23 | c.660C>A p.S220= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV100644951, COSV63434679; called by muse, mutect2, varscan2
- NIBAN3 | c.1521C>T p.V507= | Silent (SNP) | VAF 65/278 reads (23%) | catalogued as COSV99962152; called by muse, mutect2, varscan2
- PCDH19 | c.1704G>A p.L568= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV99719675; called by muse, mutect2, varscan2
- PCDHB10 | c.1275C>T p.D425= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as rs1554284172, COSV53378303, COSV99504203; called by muse, mutect2, varscan2
- RIMBP2 | c.1356G>T p.V452= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV99899360; called by muse, mutect2, varscan2
- RP1 | c.4845C>T p.G1615= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs751632799, COSV55116242, COSV99607319; called by muse, mutect2, varscan2
- RRM1 | c.1752C>T p.L584= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100331291; called by muse, mutect2, varscan2
- SKIV2L | c.1278C>T p.H426= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV100952716; called by muse, mutect2, varscan2
- SLC29A2 | c.723C>G p.L241= | Silent (SNP) | VAF 58/175 reads (33%) | catalogued as COSV100237087; called by muse, mutect2, varscan2
- SMARCC2 | c.1287C>T p.Y429= | Silent (SNP) | VAF 68/210 reads (32%) | catalogued as rs753819378, COSV57219299; called by muse, mutect2, varscan2
- WASF2 | c.108C>T p.V36= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV101420767; called by muse, mutect2, varscan2
- ZNF184 | c.123A>G p.E41= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as rs1274091366, COSV99279614; called by muse, mutect2, varscan2
- ZNF804A | c.645T>G p.S215= | Silent (SNP) | VAF 44/83 reads (53%) | catalogued as COSV56451180, COSV56458592; called by muse, mutect2, varscan2
- OR2U1P | n.811C>T | RNA (SNP) | VAF 20/66 reads (30%) | catalogued as rs1176635617; called by muse, mutect2
- SLC41A3 | c.1366+20C>G | Intron (SNP) | VAF 27/99 reads (27%) | catalogued as COSV100259580, COSV59989178; called by muse, mutect2, varscan2
- UNC5D | c.104-4788C>A | Intron (SNP) | VAF 23/96 reads (24%) | catalogued as COSV54827494, COSV99772973; called by muse, mutect2, varscan2
- WASF4P | n.1115C>A | RNA (SNP) | VAF 10/78 reads (13%) | catalogued as rs782754115; called by muse, mutect2
